TCGA case TCGA-74-6575 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Swedish Neurosciences. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/66a03e91-77c7-4aef-a825-6deef805640c

Demographics
Sex at birth: female; Age at index: 73 years; Vital status: Alive.

Diagnoses (4)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 73.4 years (26,827 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 28 days; Days to treatment end: 76 days; Treatment dose: 5,940 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 36 days; Days to treatment end: 73 days; Number of cycles: 1; Treatment dose: 4,560 mg; Prescribed dose: 120; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Recurrent Disease; Days to treatment start: 96 days; Days to treatment end: 131 days; Number of cycles: 2; Treatment dose: 2,000 mg; Prescribed dose: 200; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 152 days; Days to treatment end: 498 days (1.4 years); Number of cycles: 1; Treatment dose: 255 mg/kg; Prescribed dose: 5; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 498 days (1.4 years); Number of cycles: 1; Treatment outcome: Treatment Ongoing; Prescribed dose: 10; Prescribed dose units: mg/kg; Route of administration: Intravenous.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 73.7 years (26,920 days); Days to diagnosis: 93 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 74.7 years (27,287 days); Days to diagnosis: 460 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.
4. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 74.7 years (27,287 days); Days to diagnosis: 460 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (6 entries)
- Day 93 (post initial treatment): Progression or recurrence: Yes.
- Day 460 (post initial treatment): Progression or recurrence: Yes; Days to progression: 460 days (1.3 years).
- Days to follow up: 534 days (1.5 years); Disease response: With Tumor.
- Days to follow up: 636 days (1.7 years); Disease response: With Tumor.
- Karnofsky performance status: 70; Timepoint: Post Adjuvant Therapy.
- Karnofsky performance status: 90; Timepoint: Preoperative.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-74-6575-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.8; Intermediate dimension: 1; Shortest dimension: 0.8.
  Slide TCGA-74-6575-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-74-6575-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Regimen number: 4; Pharmaceutical therapy drug name: Avastin; Therapy regimen: Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 3; Pharmaceutical therapy drug name: Avastin; Therapy regimen: Recurrence.
- Drug treatment 3: Regimen number: 1.
- Drug treatment 3, Route of administrations: Route of administration: PO.
- Drug treatment 4: Regimen number: 2; Therapy regimen: Recurrence.
- Follow-up form 1: Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 636 days; disease-specific survival: no event (censored), 636 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 93 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-74-6575-01A-11D-1842-01): tumor purity 0.63, ploidy 1.96, whole-genome doublings 0.
